Somatic mutation profile of tumor specimen MMRF_2751_1_BM_CD138pos (aliquot MMRF_2751_1_BM_CD138pos_T1_KHS5U_L14906) from MMRF case MMRF_2751, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.6 years (19,577 days).
Specimen MMRF_2751_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0dabdb53-3815-4592-82db-cd32bf3764da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2751_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2751_1_PB_WBC_C3_KHS5U_L14907; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1b8d668-da96-4d95-8f86-a863a3932fd1

The open-access MAF lists 78 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 33, Missense Mutation 15, Intron 9, Silent 7, 5'UTR 5, Frame Shift Ins 2, Splice Site 2, Splice Region 1, 5'Flank 1, Nonsense Mutation 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*179G>T | 3'UTR (SNP) | VAF 41/78 reads (53%) | catalogued as rs75790268, CM950472; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GSDMD | c.1138+7G>A | Splice Region (SNP) | VAF 30/70 reads (43%) | catalogued as rs375275206; called by muse, mutect2, varscan2
- IGHJ5 | c.1A>T p.N1Y | Missense Mutation (SNP) | VAF 18/22 reads (82%) | PolyPhen benign (0); catalogued as rs374480186; called by muse, varscan2
- IGHV2-70 | c.261G>C p.R87S | Missense Mutation (SNP) | VAF 130/211 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs371189824; called by muse, varscan2
- IGHV2-70 | c.247T>G p.S83A | Missense Mutation (SNP) | VAF 84/254 reads (33%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.989); catalogued as rs544603085; called by muse, varscan2
- INHA | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs892484650; called by muse, mutect2, varscan2
- KDM2B | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 7/165 reads (4%) | catalogued as COSV65638138; called by muse, mutect2
- NOC2L | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58532554; called by muse, mutect2, varscan2
- PCDHGB2 | c.1222G>A p.G408S | Missense Mutation (SNP) | VAF 198/419 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.318); catalogued as rs1349523966; called by muse, mutect2, varscan2
- RCC1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 93/207 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs752749395; called by muse, mutect2, varscan2
- TRIL | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1355496818, COSV59867230; called by muse, mutect2, varscan2
- TTC23 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755761200, COSV50440532; called by muse, mutect2, varscan2
- DESI1 | c.16_26del p.L6Efs*38 | Frame Shift Del (DEL) | VAF 71/229 reads (31%) | called by mutect2, pindel, varscan2
- DEUP1 | c.1509dup p.Q504Tfs*3 | Frame Shift Ins (INS) | VAF 29/82 reads (35%) | called by mutect2, varscan2
- FOSL2 | c.698C>G p.S233C | Missense Mutation (SNP) | VAF 97/180 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- GFAP | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GLT1D1 | c.323+2T>A p.X108_splice | Splice Site (SNP) | VAF 87/168 reads (52%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.265A>G p.T89A | Missense Mutation (SNP) | VAF 66/82 reads (80%) | SIFT deleterious (0.05); PolyPhen benign (0.108); called by muse, varscan2
- MATN4 | c.336G>T p.M112I | Missense Mutation (SNP) | VAF 69/136 reads (51%) | PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PCDH15 | c.4969G>A p.G1657R | Missense Mutation (SNP) | VAF 259/498 reads (52%) | SIFT deleterious, low confidence (0.01); called by mutect2, varscan2
- PDE8A | c.1185+1G>A p.X395_splice | Splice Site (SNP) | VAF 65/139 reads (47%) | called by muse, mutect2, varscan2
- SPAG6 | c.1230dup p.C411Mfs*8 | Frame Shift Ins (INS) | VAF 51/129 reads (40%) | called by mutect2, pindel, varscan2
- TMED2 | c.451A>G p.M151V | Missense Mutation (SNP) | VAF 85/211 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- ENPP3 | c.1756C>T p.L586= | Silent (SNP) | VAF 125/346 reads (36%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.282C>T p.S94= | Silent (SNP) | VAF 70/86 reads (81%) | catalogued as rs547382671; called by muse, varscan2
- IQGAP3 | c.2643A>T p.V881= | Silent (SNP) | VAF 40/98 reads (41%) | called by muse, mutect2, varscan2
- KLHL26 | c.237C>G p.V79= | Silent (SNP) | VAF 68/131 reads (52%) | catalogued as COSV56317399; called by muse, mutect2, varscan2
- MYH10 | c.4275G>A p.L1425= | Silent (SNP) | VAF 15/184 reads (8%) | called by muse, mutect2
- OR8J1 | c.132C>A p.G44= | Silent (SNP) | VAF 177/327 reads (54%) | called by muse, mutect2, varscan2
- YARS1 | c.327T>G p.G109= | Silent (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- ADCY5 | c.*79G>A | 3'UTR (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- AP1M2 | c.-26G>A | 5'UTR (SNP) | VAF 54/137 reads (39%) | called by muse, mutect2, varscan2
- ARID3A | c.*42G>A | 3'UTR (SNP) | VAF 8/10 reads (80%) | catalogued as rs1211331300; called by muse, mutect2, varscan2
- ARL14EP | c.*1243G>T | 3'UTR (SNP) | VAF 46/101 reads (46%) | called by muse, mutect2, varscan2
- ATP9A | c.*4693G>A | 3'UTR (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- BEGAIN | c.*109A>G | 3'UTR (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- BICC1 | c.*365G>C | 3'UTR (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
- BRAT1 | c.431-55C>T | Intron (SNP) | VAF 38/62 reads (61%) | called by muse, mutect2, varscan2
- C1orf87 | c.1192+1744G>A | Intron (SNP) | VAF 5/107 reads (5%) | called by muse, mutect2
- CASZ1 | c.*54G>A | 3'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- CCDC6 | c.*2599C>T | 3'UTR (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- CHM | c.*2503T>A | 3'UTR (SNP) | VAF 49/97 reads (51%) | called by muse, mutect2, varscan2
- CHORDC1 | c.*1066G>A | 3'UTR (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- COG6 | c.623+62T>C | Intron (SNP) | VAF 37/40 reads (93%) | called by muse, mutect2, varscan2
- ERC1 | c.*1858C>T | 3'UTR (SNP) | VAF 7/96 reads (7%) | catalogued as rs1565549749; called by muse, mutect2
- ERRFI1 | c.*996T>G | 3'UTR (SNP) | VAF 38/84 reads (45%) | called by muse, varscan2
- ERRFI1 | c.*955T>A | 3'UTR (SNP) | VAF 39/84 reads (46%) | called by muse, varscan2
- ETV6 | c.328+1449T>G | Intron (SNP) | VAF 37/46 reads (80%) | catalogued as rs989004286; called by muse, mutect2, varscan2
- FBXW7 | c.1645-118T>C | Intron (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- FREM2 | c.*4755G>A | 3'UTR (SNP) | VAF 40/48 reads (83%) | called by muse, mutect2, varscan2
- FRMPD3 | c.*970T>G | 3'UTR (SNP) | VAF 61/110 reads (55%) | called by muse, mutect2, varscan2
- GDI2 | c.-150C>T | 5'UTR (SNP) | VAF 41/72 reads (57%) | called by muse, mutect2, varscan2
- GRIK4 | c.907-2163T>C | Intron (SNP) | VAF 124/293 reads (42%) | called by muse, mutect2, varscan2
- HHEX | c.*272_*275del | 3'UTR (DEL) | VAF 19/37 reads (51%) | catalogued as rs1297215692; called by mutect2, pindel, varscan2
- IFNAR2 | c.*1253C>T | 3'UTR (SNP) | VAF 60/93 reads (65%) | called by muse, mutect2, varscan2
- LARP4B | c.*1472A>G | 3'UTR (SNP) | VAF 58/116 reads (50%) | called by muse, mutect2, varscan2
- LHX5 | chr12:113471885 T>C | 5'Flank (SNP) | VAF 82/159 reads (52%) | called by muse, mutect2, varscan2
- LY6H | c.68-100C>T | Intron (SNP) | VAF 18/34 reads (53%) | catalogued as COSV61371421; called by muse, mutect2, varscan2
- MINDY2 | c.*5390G>A | 3'UTR (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- NKIRAS2 | c.*1236T>C | 3'UTR (SNP) | VAF 41/98 reads (42%) | called by muse, mutect2, varscan2
- OTC | c.*167T>A | 3'UTR (SNP) | VAF 61/113 reads (54%) | called by muse, mutect2, varscan2
- PGR | c.*5242C>G | 3'UTR (SNP) | VAF 50/92 reads (54%) | called by muse, mutect2, varscan2
- PLA2R1 | c.*648C>T | 3'UTR (SNP) | VAF 41/88 reads (47%) | called by muse, mutect2, varscan2
- POLDIP3 | c.*1473C>T | 3'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- PPP1R26 | c.-62-34C>T | Intron (SNP) | VAF 77/166 reads (46%) | catalogued as rs1368545447; called by muse, mutect2, varscan2
- RHPN2P1 | n.1715G>A | RNA (SNP) | VAF 58/679 reads (9%) | catalogued as rs1452344426; called by muse, mutect2
- SDC3 | c.*55G>A | 3'UTR (SNP) | VAF 25/70 reads (36%) | called by muse, mutect2, varscan2
- SENP5 | c.*2443T>A | 3'UTR (SNP) | VAF 25/31 reads (81%) | called by muse, mutect2, varscan2
- SERINC5 | c.-69G>A | 5'UTR (SNP) | VAF 31/67 reads (46%) | called by muse, mutect2, varscan2
- SFTPA1 | c.*405_*406insCTGCCTGCCCA | 3'UTR (INS) | VAF 5/62 reads (8%) | called by mutect2*, pindel
- SGCE | c.1145+24A>T | Intron (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- SMDT1 | c.-64C>G | 5'UTR (SNP) | VAF 10/26 reads (38%) | catalogued as rs1220742752; called by muse, varscan2
- SYNCRIP | c.*357T>C | 3'UTR (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- TMED7-TICAM2 | c.*1658T>C | 3'UTR (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- TNFSF15 | c.*597T>A | 3'UTR (SNP) | VAF 57/104 reads (55%) | called by muse, mutect2, varscan2
- UBTD2 | c.-23C>T | 5'UTR (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- VAMP8 | c.*195A>C | 3'UTR (SNP) | VAF 67/208 reads (32%) | called by muse, mutect2, varscan2
- ZNF792 | c.*1265T>C | 3'UTR (SNP) | VAF 51/111 reads (46%) | called by muse, mutect2, varscan2
